Gene-level copy-number profile of specimen HCM-CSHL-0374-C25-85A from HCMI case HCM-CSHL-0374-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Intraductal papillary-mucinous carcinoma, invasive; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 74.7 years (27,272 days).
Specimen HCM-CSHL-0374-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 17.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5327b0ec-5f35-402d-97a1-56ecfc070b36.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0374-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/8a12c387-9a57-424f-a0ba-08e99a97bd3c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 870; copy number 2: 10,914; copy number 3: 11,478; copy number 4: 27,520; copy number 5: 6,789; copy number 6: 380; copy number 7: 161; copy number 8: 217; copy number 9: 351; copy number 10: 114; copy number 11: 49; copy number 12: 51; copy number 13: 9; copy number 14: 2; copy number 16: 4; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 581 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:40,391,591–44,380,179, 144 genes, copy number 9–11 (broad region; genes not listed).
- chr6:44,513,262–45,377,953, 4 genes, copy number 9–11 (within-gene range 2–11): AL136140.1, AL136140.2, AL133334.1, SUPT3H.
- chr6:45,097,496–45,664,349, 7 genes, copy number 10–11: AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1.
- chr19:30,219,666–31,427,302, 12 genes, copy number 10–17: AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1.
- chr19:31,787,148–32,676,597, 13 genes, copy number 9 (within-gene range 8–9): RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31.
- chr19:32,719,753–32,829,580, 2 genes, copy number 9: TDRD12, AC008805.1.
- chr19:33,177,603–33,208,864, 1 gene, copy number 9 (within-gene range 8–9): LRP3.
- chr19:33,207,129–33,225,850, 3 genes, copy number 9: AC008738.7, SLC7A10, AC008738.4.
- chr19:33,340,686–33,521,791, 4 genes, copy number 9: RPS3AP50, AKR1B1P7, CEBPG, PEPD.
- chr19:33,906,352–33,927,625, 2 genes, copy number 9: AC008556.1, RN7SL150P.
- chr19:34,092,561–34,229,515, 3 genes, copy number 9: RPS4XP21, CHCHD2P3, LSM14A.
- chr19:34,533,427–34,945,170, 25 genes, copy number 9: RPS26P55, ZNF807P, SCGB1B2P, SCGB2B2, AC020910.4, AC020910.1, AC020910.2, AC020910.7, SCGB2B3P, AC020910.6, ZNF302, AC020910.5, ZNF181, ZNF599, AC020910.3, LINC01801, AC008555.1, AC008555.5, AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1, ZNF30.
- chr19:34,994,784–35,066,571, 5 genes, copy number 10–13 (within-gene range 8–13): GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN.
- chr19:35,533,455–35,684,201, 14 genes, copy number 9: GAPDHS, TMEM147-AS1, TMEM147, ATP4A, AD000090.1, LINC01766, AC002115.1, HAUS5, RBM42, ETV2, COX6B1, UPK1A, UPK1A-AS1, TYMSP2.
- chr19:36,259,540–36,331,770, 2 genes, copy number 9: LINC00665, AC092296.2.
- chr19:36,383,120–36,777,078, 17 genes, copy number 9: ZFP82, AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2.
- chr19:37,128,679–37,141,640, 1 gene, copy number 9 (within-gene range 7–9): AC012309.2.
- chr19:37,312,837–37,369,365, 1 gene, copy number 9 (within-gene range 8–9): ZNF875.
- chr19:37,337,236–37,855,215, 23 genes, copy number 9: AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1.
- chr19:38,409,051–38,587,564, 2 genes, copy number 9 (within-gene range 7–9): RASGRP4, RYR1.
- chr19:38,915,266–38,975,742, 5 genes, copy number 9 (within-gene range 7–9): SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17.
- chr19:39,125,770–39,204,263, 4 genes, copy number 9: PAK4, AC011443.1, NCCRP1, SYCN.
- chr19:39,246,314–39,435,949, 16 genes, copy number 9: IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16.
- chr19:39,515,113–39,738,029, 22 genes, copy number 9: SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC.
- chr19:39,863,323–41,128,381, 63 genes, copy number 9–14 (broad region; genes not listed).
- chr19:41,449,520–43,171,515, 74 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr19:43,035,869–43,304,523, 10 genes, copy number 9: CEACAMP8, PSG2, CEACAMP9, AC005392.1, PSG5, PSG4, CEACAMP10, PSG9, CEACAMP11, CEACAMP4.
- chr19:43,460,787–44,536,613, 60 genes, copy number 9–10 (within-gene range 9–11): LYPD3, PHLDB3, ETHE1, ZNF575, XRCC1, L34079.2, L34079.1, L34079.3, PINLYP, IRGQ, ZNF576, SRRM5, ZNF428, CADM4, PLAUR, RN7SL368P, IRGC, SMG9, KCNN4, LYPD5, AC115522.1, ZNF283, ZNF404, AC006213.6, AC006213.2, AC006213.7, AC006213.3, ZNF45, ZNF221, ZNF155, AC006213.4, AC006213.5, AC006213.1, ZNF230, AC067968.2, ZNF222, AC067968.1, ZNF223, ZNF284, RNU6-902P, ZNF224, AC021092.1, ZNF225, ZNF234, ZNF226, ZNF227, ZNF235, AC138470.1, ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3.
- chr19:45,178,784–45,216,933, 1 gene, copy number 9 (within-gene range 8–9): BLOC1S3.
- chr19:45,733,439–45,974,044, 15 genes, copy number 9: BHMG1, SIX5, AC074212.1, DM1-AS, DMPK, AC011530.1, DMWD, RSPH6A, SYMPK, AC092301.1, FOXA3, IRF2BP1, MYPOP, NANOS2, NOVA2.
- chr19:46,019,153–46,023,053, 1 gene, copy number 9 (within-gene range 7–9): PGLYRP1.
- chr19:46,039,748–46,413,564, 22 genes, copy number 9: IGFL4, AC007785.1, AC007785.2, IGFL3, TGIF1P1, IGFL2, AC006262.2, IGFL2-AS1, IGFL1P1, AC006262.1, RPL12P41, AC006262.3, IGFL1, AC006262.4, IGFL1P2, HIF3A, RNU6-924P, AC007193.2, PPP5C, AC007193.1, AC007193.3, CCDC8.
- chr19:46,719,511–46,746,994, 3 genes, copy number 9 (within-gene range 8–9): STRN4, AC008635.1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 410. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
